TCGA case TCGA-KO-8403 — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/648fecca-4946-4880-8359-6801cbb4fc0d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, chromophobe type: ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 49.7 years (18,171 days); Year of diagnosis: 2005; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 3,208 days (8.8 years).
   Pathology details: Consistent pathology review: Yes; Sarcomatoid present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 2,339 days (6.4 years); Disease response: Tumor Free.
- Days to follow up: 3,208 days (8.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Platelets: Normal.
- Hemoglobin: Normal.
- Leukocytes: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KO-8403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.8; Shortest dimension: 0.7.
  Slide TCGA-KO-8403-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-KO-8403-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Sample TCGA-KO-8403-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KO-8403-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 3; Intermediate dimension: 0.8; Shortest dimension: 0.8.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Sarcomatoid features: No; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,208 days; disease-specific survival: no event (censored), 3,208 days; progression-free interval: no event (censored), 3,208 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KO-8403-01A-11D-2308-01): tumor purity 0.76, ploidy 1.64, whole-genome doublings 0.
